Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4803, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4803-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4803

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Incidentally detected 5 cm right renal mass. Right renal mass.

Specimens Submitted:

1: SP: Right renal tumor; partial nephrectomy

DIAGNOSIS:

1. SP: Right renal tumor; partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
Areas of geographic necrosis are present.

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.8 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Cortical scar and mild arteriosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation, labeled "right renal tumor, stitch-deep surgical margin". It consists of a 254 g, 16 x 14 x 5 cm wedge shaped portion of kidney and perinephric adipose tissue with a suture marking the deep margin. The kidney itself measures 6 x 5.5 x 4.7 cm. The margin is inked green and perinephric adipose tissue overlying the kidney is inked black. Specimen is serially sectioned to reveal a 4.8 x 4.4 x 4.0 cm wall-circumscribed tumor with a soft, yellow cut surface with areas of hemorrhage and necrosis. The clearance from the resection margin is 0.1 cm. The tumor is distending but does not appear to invade through the capsule into the adipose tissue. Representative sections of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSCA - frozen section control A

FSCB - frozen section control B

T - tumor

TM - additional sections of tumor and margin

TP - tumor and perinephric adipose tissue

TK - tumor and adjacent kidney

Summary of Sections:

Part 1: SP: Right renal tumor; partial nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	fsca	1
1	fsch	1
4	t	4
1	tk	1
1	tm	1
3	tp	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RIGHT RENAL TUMOR [REDACTED]: RENAL CORTICAL NEOPLASM PRESENT WITHIN 1 MM OF THE INKED MARGIN [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file 71b79096-c15b-4aed-945f-d7df7d78daff (TCGA-BP-4803.1D68F214-1D32-45F7-82F6-BC9FB433A970.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).